Somatic mutation profile of tumor specimen 0D9DR3 from CCDI case PBBIJS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.5 years (2,377 days).
Specimen 0D9DR3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ee8389a-065f-4127-bb64-3d66d9cc03e2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0D9DR4 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b8ceff28-4bf3-4fd3-bf04-283bcf3f195e

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GRIP1 | c.374G>A p.G125E | Missense Mutation (SNP) | VAF 56/952 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.94); catalogued as COSV54025572; called by muse, mutect2
- STAT5B | c.1976G>T p.R659L | Missense Mutation (SNP) | VAF 43/1010 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99510716; called by muse, mutect2
- MIER3 | c.1135G>T p.E379* (on ENST00000381199 / NM_001297599.2; = p.E378* on NM_152622.4) | Nonsense Mutation (SNP) | VAF 80/1174 reads (7%) | called by muse, mutect2
